Surgical pathology report (de-identified scan), TCGA case TCGA-66-2758, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2758-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left upper lobe, and others

Clinical diagnosis and question

Space-occupying lesion left upper lobe S3, EG: 06/06, status post-op. for prostate carcinoma, hitherto no chemotherapy; histology: large-cell and partly polymorphocellular squamous cell carcinoma.

REPORT ON FINDINGS**Macroscopy**

- 1.) Apical pleura I: tissue measuring 2.3 x 0.8 cm and up to 0.4 cm thick with whitish vitreous section surfaces.
- 2.) Apical pleura II: 0.5 cm flat, pale reddish tissue.
- 3.) S6: 0.3 cm brownish-gray particle, on one side questionable pleura and 0.3 cm piece of tissue.
- 4.) Lobar LN (station 12) lower lobe: 0.5 cm partly blackish, partly reddish portion of node.
- 5.) Left upper lobe: inflated, fixed left upper lobe measuring 23 x 14 x 8 cm, central bronchus resection plane located just proximal to the bifurcation of the lingular bronchus. A 4.5 cm long branched staple suture line in the dorsal region of the hilus. A 1.5 cm mobile, grayish-black node at the hilus. In the lateral boundary region of segments 1, 2 and 3, an area of the parietal pleura, measuring 15 x max. 5 cm, shows a plate-like increase up to a thickness of 0.5 cm, extensively adhesive in parts and loosely attached in other parts. Segments 2 and 3 and also adjacent segments of S1 largely occupied by a soft to moderately hard, centrally disintegrated pale-brownish tumor, max. 9 cm in size, with a relatively clear and vaguely arcuate demarcation and yellowish areas. Tumor extension to the pleura in the region of the adhesion and to within 0.5 cm of the hilar resection surface, with uncertain involvement of central nodes by the tumor. Truncation of intermediate parts of B1, B2 and B3 in the tumor. Focal tumor spread to the medial pleura over S2, where there is a 0.5 cm crack in the surface and suture material. Pleura in the vicinity is roughened or damaged and shows patchy dark discoloration. Parenchyma in the tumor environment partly indurated and of brownish-yellow color, same type of changes in segment 4.
- 6.) Lobar LN (station 12) lingula: 1.6 cm lesioned grayish-black node or node part.
- 7.) Interlobar LN (station 11) left: 0.4 cm node or node part.
- 8.) Hilar LN (station 10) left: three lesioned grayish-black nodes or node parts between 0.4 cm and 0.7 cm in size.
- 9.) Subcarinal LN (station 7) left: 1.1 cm lesioned grayish-black node.
- 10.) Paraaortic LN (station 6) left: 1.8 cm lesioned node.
- 11.) Subaortic LN (aortopulmonary window) (station 5) left: 2 cm lesioned node part.

Examined:

- 1.) Rapid section remains + residual material.
- 2.) - 4.) Rapid section remains in each case.
- 5.) Tumor and remaining parenchyma with intermediate section of B3, 4 sections with pleura in the region of the adhesion zone, 2 sections of hilar resection surface (color marking), 2 sections in the region of the truncation, S1/S3 peripheral, S4, hilar node (lamellated), 4 further sections with parabronchial nodes,
- 6.) -11.) All material (in 10.) and 11.) preparations halved in each case),
- 23 blocks, partly [REDACTED], PAS and also PAS with diastase staining.

[page 2 of 2]
Microscopy

Re 1.) and 2.) Immediate intraoperative evaluation (): fibrosis and slight chronic inflammation, no evidence of carcinoma.

Re 3.) Immediate intraoperative evaluation (): small portion of a large-cell solid carcinoma at the margin of a chronic organizing inflammation.

Re 4.) Immediate intraoperative evaluation (): small lymph node without evidence of tumor.

Re 5.) Immediate intraoperative evaluation () bronchus resection margin tumor-free.

Description of histological and cytological findings omitted for capacity reasons.

EVALUATION**Primary diagnosis/diagnoses:**

Large, bronchopulmonary, large-cell, polymorphocellular and partly gigantocellular, barely keratinizing squamous cell carcinoma ranging from intermediate to peripheral, histologically poorly differentiated, in the upper lobe of the left lung with localization in the boundary region of segments 1-3.

TNM classification according to this picture pT2 pN0 pMX V1 RX, stage IB

C34.1 M8070/3.

Secondary diagnosis/diagnoses:

Tumor necroses. Ectasia of small bronchial branches peripheral to the tumor with moderately marked chronic inflammation. Focal, chronic organizing and focally fibrinous pneumonia at tumor margin, peripheral to the tumor in S1/3 and S4 (sample 5.)). Soft-tissue particles with chronic fibrosing inflammation (samples 1.) and 2.)). Lymph nodes with uncharacteristic reactive lesions and anthracotic pigment deposits (samples 4.) - 11.)).

Remark/addendum:

The tumor extends peripherally to the visceral pleura in the area of adhesion with the parietal layer, there is no evidence here to suggest infiltration of the visceral pleura. Over S2 there is a pleural defect; the tumor here shows a circumscribed extension to the preparation surface, and a further small part of the tumor is contained in sample 3.), so from a patho-anatomical perspective a category of RX is arrived at. The resection margin of the bronchus and vessels and also all the lymph nodes removed and identified are tumor-free.

Material examined:

Left upper lobe, and others

1. Additional report

After consultation by phone () the origin of the resected tissue of sample 3.) must be corrected. The particle comes from S2.

Source: NCI Genomic Data Commons file a657e792-2d83-4173-ae35-e38dd38a126c (TCGA-66-2758.C35772E8-176C-4572-80BD-E4EA7BD0684D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).